Somatic mutation profile of tumor specimen TCGA-17-Z004-01A (aliquot TCGA-17-Z004-01A-01W-0746-08) from TCGA case TCGA-17-Z004, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z004-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a889c655-2d38-42ad-b7db-7cd66043fe43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z004-11A (Solid Tissue Normal), aliquot TCGA-17-Z004-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/323ca078-aeb1-42c1-9499-233b303a31d6

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Intron 1, Splice Region 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.2885C>G p.P962R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs892822263; called by muse, mutect2, varscan2
- ARHGAP15 | c.605T>C p.L202P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs1251780866; called by muse, mutect2, varscan2
- METTL21C | c.520dup p.E174Gfs*15 | Frame Shift Ins (INS) | VAF 6/43 reads (14%) | catalogued as rs760847518; called by pindel, varscan2
- MTMR7 | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs201283564; called by muse, mutect2, varscan2
- RNF115 | c.64T>C p.C22R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1553724933; called by muse, varscan2
- THAP4 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs758509664; called by muse, mutect2, varscan2
- TRPV1 | c.2120T>G p.L707R | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1237713384; called by muse, mutect2
- CCR1 | c.557A>G p.H186R | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUSK | c.160T>C p.Y54H | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.929); called by muse, varscan2
- OR8K3 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- PRKDC | c.2935G>T p.V979L | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SBF1 | c.1007G>A p.S336N | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- SLCO4C1 | c.897A>G p.E299= | Splice Region (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2, varscan2
- ZNF407 | c.1054A>T p.R352* | Nonsense Mutation (SNP) | VAF 28/63 reads (44%) | called by muse, mutect2, varscan2
- ZNF600 | c.247A>C p.I83L | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by mutect2, varscan2
- ABR | c.378C>G p.T126= (on ENST00000302538 / NM_021962.5; = p.T89= on NM_001092.5) | Silent (SNP) | VAF 42/89 reads (47%) | called by muse, varscan2
- C2CD5 | c.2820C>G p.V940= | Silent (SNP) | VAF 32/82 reads (39%) | called by muse, varscan2
- RAD54L2 | c.2676A>G p.L892= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs1471531502; called by muse, mutect2, varscan2
- SLIT2 | c.3900C>T p.N1300= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs141395818, COSV56593779; called by muse, mutect2, varscan2
- STAB2 | c.4065C>G p.V1355= | Silent (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- TTC37 | c.3426A>G p.K1142= | Silent (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- PDE4D | c.455+124835T>A | Intron (SNP) | VAF 20/98 reads (20%) | catalogued as rs1266222641; called by muse, mutect2, varscan2
